Somatic mutation profile of tumor specimen TCGA-B8-A54G-01A (aliquot TCGA-B8-A54G-01A-11D-A25V-10) from TCGA case TCGA-B8-A54G, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 51.0 years (18,612 days).
Specimen TCGA-B8-A54G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7079747e-948f-40fe-92c7-44ce5fd00016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54G-10A (Blood Derived Normal), aliquot TCGA-B8-A54G-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c84c10bd-3f47-41f8-8417-0bdd6584f8a2

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 28, Silent 9, In Frame Del 2, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 48/156 reads (31%) | catalogued as rs387906848, CM117949, COSV56230282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV100609531; called by muse, mutect2, varscan2
- ADGRV1 | c.12025G>A p.A4009T | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101316579; called by muse, mutect2, varscan2
- AKNAD1 | c.621C>A p.S207R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100645905; called by muse, mutect2, varscan2
- ATP8B3 | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs764851413, COSV59544240; called by muse, mutect2, varscan2
- BMT2 | c.340A>C p.K114Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV99774887; called by muse, mutect2, varscan2
- CTSA | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1244064907, COSV99510166; called by muse, mutect2, varscan2
- EIF2AK1 | c.914T>A p.V305E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99552376; called by muse, mutect2, varscan2
- FAM83G | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs868244855, COSV58755838; called by muse, varscan2
- FARP2 | c.1528A>T p.S510C | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99885639; called by muse, varscan2
- FES | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183393; called by muse, mutect2, varscan2
- GLG1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.173); catalogued as COSV52673131, COSV99216318; called by muse, mutect2
- GRIP1 | c.1964G>A p.R655H (on ENST00000359742 / NM_001379345.1; = p.R603H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs200688707, COSV54025919; called by muse, mutect2, varscan2
- NAALAD2 | c.1076A>T p.D359V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428866; called by muse, mutect2, varscan2
- OGDH | c.2138A>G p.Y713C | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367952650; called by muse, mutect2, varscan2
- PCDHAC2 | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs782606184, COSV99163267; called by muse, mutect2, varscan2
- PIP5K1C | c.1058T>A p.L353H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100096151; called by muse, mutect2, varscan2
- PLEKHM3 | c.1589T>A p.V530E | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101216928; called by muse, mutect2, varscan2
- PTBP1 | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100609155; called by muse, mutect2, varscan2
- PTPRT | c.838T>A p.Y280N | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100630767, COSV99049476; called by muse, mutect2, varscan2
- RYR2 | c.13010C>T p.P4337L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100773113, COSV63680248, COSV63701662; called by muse, mutect2
- SEMA4A | c.1434+2T>C p.X478_splice | Splice Site (SNP) | VAF 19/100 reads (19%) | catalogued as COSV100740748; called by muse, mutect2, varscan2
- SLC30A3 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99273922; called by muse, mutect2
- SLC35A2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99504593; called by muse, mutect2, varscan2
- TREH | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99874831; called by muse, mutect2, varscan2
- TRIM67 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); catalogued as COSV100792222; called by muse, mutect2, varscan2
- TRPM2 | c.2500C>T p.L834F | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100309362; called by muse, mutect2, varscan2
- ZNF285 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1278422324, COSV58409473; called by muse, mutect2, varscan2
- IGHV1-45 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGKV1-16 | c.69_70dup p.I24Tfs*4 | Frame Shift Ins (INS) | VAF 28/190 reads (15%) | called by pindel, varscan2
- IGKV1D-16 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 73/436 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- NPAS4 | c.293_294del p.S98* | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- RPAIN | c.407_421del p.I136_C140del | In Frame Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel
- SSR4 | c.337_342del p.S113_L114del | In Frame Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ARRB1 | c.537C>T p.G179= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV63576375; called by muse, mutect2, varscan2
- DBH | c.1602C>G p.S534= | Silent (SNP) | VAF 54/214 reads (25%) | catalogued as COSV101257214; called by muse, varscan2
- GLRB | c.879C>T p.D293= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs201323247, COSV52418766; called by muse, mutect2
- HSD17B10 | c.12G>A p.A4= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV99395116; called by muse, mutect2, varscan2
- MORC4 | c.2247A>C p.A749= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV99717651; called by muse, mutect2
- NFRKB | c.1983G>A p.R661= (on ENST00000446488 / NM_001143835.2; = p.R686= on NM_006165.3) | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV58759520; called by muse, mutect2, varscan2
- PRSS27 | c.861C>T p.G287= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs201002896, COSV57013234; called by muse, mutect2
- REC8 | c.1527G>A p.R509= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100269251; called by muse, mutect2
- TMEM67 | c.1500C>T p.A500= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV100019969; called by muse, mutect2, varscan2
